CCDI case PBBLSD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/109fb41e-a1ac-45c1-8817-4374a7c8bec3

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Craniopharyngioma, adamantinomatous: ICD-O-3 morphology code: 9351/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.5 years (2,731 days).

Biospecimens (3 samples)
- Sample 0DBSCW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DBSCX, 0DBSCY (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
